Gene-level copy-number profile of tumor specimen ALCH-B2TF-TTP1-A from ALCHEMIST case ALCH-B2TF, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.8 years (24,047 days).
Specimen ALCH-B2TF-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 23ec9140-0c10-4688-ba52-919278a45273.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2TF-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/80b226ce-5f7f-4da1-984d-4098a8246c4b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7; copy number 2: 1,091; copy number 3: 7,727; copy number 4: 40,183; copy number 5: 1,371; copy number 6: 6,970; copy number 7: 129; copy number 8: 230; copy number 9: 681; copy number 10: 8; copy number 17: 1.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:13,317,428–13,348,298, 1 gene: SEPHS1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 690 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:37,032–39,493,095, 680 genes, copy number 9 (broad region; genes not listed).
- chr7:63,011,463–63,011,569, 1 gene, copy number 10: RNU6-417P.
- chr11:1,554,051–1,572,271, 1 gene, copy number 9 (within-gene range 4–9): DUSP8.
- chr13:112,313,467–112,321,758, 1 gene, copy number 17: LINC01043.
- chr16:90,093,154–90,222,851, 7 genes, copy number 10: TUBB8P7, FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.

Autosomal genes at a single copy (total copy number 1): 7. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
